Somatic mutation profile of tumor specimen TCGA-UZ-A9PL-01A (aliquot TCGA-UZ-A9PL-01A-11D-A382-10) from TCGA case TCGA-UZ-A9PL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II.
Specimen TCGA-UZ-A9PL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d3aae76-81dd-4f53-a076-b6f7572e1a06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PL-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PL-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f248f5d-8419-4a5c-8560-3135c0e9ce35

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Frame Shift Del 8, Intron 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 101/154 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99366194; called by muse, mutect2, varscan2
- ACSM2A | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99525239; called by muse, mutect2, varscan2
- ADAMTS1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99536119; called by muse, mutect2, varscan2
- ADGRV1 | c.9713A>G p.Q3238R | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV101315951; called by muse, mutect2, varscan2
- AP3B1 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1396289255, COSV99671356; called by muse, mutect2, varscan2
- ATP10D | c.4042A>G p.K1348E | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV99903629; called by muse, mutect2, varscan2
- BTRC | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100926556; called by muse, mutect2, varscan2
- C3orf20 | c.2495G>A p.S832N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1046269084, COSV99513944; called by muse, mutect2, varscan2
- C3orf20 | c.2495+1G>C p.X832_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99513945; called by muse, mutect2, varscan2
- C6 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54707809; called by muse, mutect2, varscan2
- CFHR4 | c.1654G>A p.G552R (on ENST00000367416 / NM_001201551.2; = p.G306R on NM_006684.5) | Missense Mutation (SNP) | VAF 177/423 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV99260428; called by muse, mutect2, varscan2
- CHD6 | c.2715T>A p.Y905* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV100498258; called by muse, mutect2, varscan2
- CREB1 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV100783581; called by muse, mutect2, varscan2
- DBF4B | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs202196229, COSV100154515; called by muse, mutect2, varscan2
- DFFB | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100138690; called by muse, mutect2, varscan2
- DIAPH1 | c.2640G>C p.E880D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99526564; called by muse, mutect2, varscan2
- DNM2 | c.2444C>A p.P815H (on ENST00000355667 / NM_001005360.3; = p.P811H on NM_004945.3) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99284144; called by muse, mutect2, varscan2
- ESPL1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs200673617, COSV99229310; called by muse, mutect2, varscan2
- HCN1 | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as COSV100300222; called by muse, mutect2, varscan2
- IFIT2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs777976445, COSV51079114; called by muse, mutect2, varscan2
- KBTBD8 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805663; called by muse, mutect2, varscan2
- LATS1 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99485996; called by muse, mutect2, varscan2
- LRRC8D | c.2268T>G p.H756Q | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100487251; called by muse, mutect2, varscan2
- MADD | c.2035C>A p.Q679K | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as COSV100211035; called by muse, mutect2, varscan2
- MAP3K12 | c.1445A>G p.H482R | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV99913257; called by muse, mutect2, varscan2
- MGAM | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV101516426; called by muse, mutect2, varscan2
- NPVF | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs201924062; called by muse, mutect2, varscan2
- OR11H12 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV101612490; called by muse, mutect2, varscan2
- OTOGL | c.1420T>C p.C474R (on ENST00000547103; = p.C465R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237798998, COSV101509259; called by muse, mutect2, varscan2
- PLEKHA6 | c.2493C>A p.H831Q | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99692016; called by muse, mutect2, varscan2
- PPP1R13L | c.1855A>G p.K619E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV100714755; called by muse, mutect2, varscan2
- RGS17 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 54/114 reads (47%) | catalogued as COSV99242885; called by muse, mutect2, varscan2
- RNF139 | c.1881G>C p.R627S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99413400; called by muse, mutect2, varscan2
- SCG2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100544718; called by muse, mutect2, varscan2
- SEC16A | c.3477C>A p.Y1159* | Nonsense Mutation (SNP) | VAF 79/144 reads (55%) | catalogued as COSV99258098; called by muse, mutect2, varscan2
- SELENOP | c.760A>G p.R254G | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.44); catalogued as COSV100736838; called by muse, mutect2, varscan2
- SMPD3 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs755188485, COSV99545658; called by muse, mutect2, varscan2
- SPEG | c.3880G>A p.V1294M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100404476; called by muse, mutect2, varscan2
- SPG11 | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99968643; called by muse, mutect2, varscan2
- SPOCD1 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs770934272, COSV57096152; called by muse, mutect2, varscan2
- SYNE2 | c.16679T>A p.L5560H | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV100647662; called by muse, mutect2, varscan2
- TLN2 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100169001; called by muse, mutect2, varscan2
- TMEM121B | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV100083132; called by muse, mutect2, varscan2
- ZNF556 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100298734; called by muse, mutect2, varscan2
- CCDC83 | c.1087_1088dup p.N364* (on ENST00000342404 / NM_001286159.2; = p.N395* on NM_173556.5) | Frame Shift Ins (INS) | VAF 74/172 reads (43%) | called by mutect2, varscan2
- DZIP1 | c.1795del p.E599Nfs*35 (on ENST00000347108; = p.E580Nfs*35 on NM_014934.5) | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- FAM13B | c.1275dup p.L426Ifs*9 | Frame Shift Ins (INS) | VAF 136/369 reads (37%) | called by mutect2, pindel, varscan2
- FLRT2 | c.1613del p.G538Afs*9 | Frame Shift Del (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- GPALPP1 | c.718del p.A240Qfs*45 | Frame Shift Del (DEL) | VAF 138/392 reads (35%) | called by mutect2, pindel, varscan2
- LRIG3 | c.909_915del p.S303Rfs*14 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.1346_1353del p.K449Ifs*21 (on ENST00000456763 / NM_001128608.2; = p.K443Ifs*21 on NM_014994.3) | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.58dup p.V20Gfs*18 | Frame Shift Ins (INS) | VAF 62/136 reads (46%) | called by mutect2, varscan2
- SLCO1C1 | c.245del p.G82Efs*13 | Frame Shift Del (DEL) | VAF 68/149 reads (46%) | called by mutect2, pindel, varscan2
- TNFSF8 | c.659_665del p.P220Rfs*69 | Frame Shift Del (DEL) | VAF 32/69 reads (46%) | called by mutect2, pindel, varscan2
- UMPS | c.1027_1032del p.H343_V344del | In Frame Del (DEL) | VAF 72/162 reads (44%) | called by mutect2, pindel*, varscan2*
- UQCRC1 | c.1328_1334del p.E443Afs*70 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- AHI1 | c.831T>C p.H277= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1468647725, COSV99662722; called by muse, mutect2, varscan2
- ANKZF1 | c.1413A>G p.S471= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV99850541; called by muse, mutect2, varscan2
- BDP1 | c.1938A>G p.S646= | Silent (SNP) | VAF 158/337 reads (47%) | catalogued as COSV100703071; called by muse, mutect2, varscan2
- C9orf43 | c.499C>T p.L167= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV55912675, COSV99928351; called by muse, mutect2, varscan2
- EPHA7 | c.1050A>G p.E350= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs760697329, COSV100993700; called by muse, mutect2, varscan2
- GLG1 | c.2169G>A p.Q723= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV99215765; called by muse, mutect2, varscan2
- GRIK2 | c.318C>T p.I106= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs1476303944, COSV100026075; called by muse, mutect2, varscan2
- MAP3K7 | c.30C>G p.S10= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100997933; called by muse, mutect2, varscan2
- RHOBTB1 | c.267T>C p.H89= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100558471; called by muse, mutect2, varscan2
- SEMA4C | c.168G>A p.L56= | Silent (SNP) | VAF 69/163 reads (42%) | catalogued as COSV100560962; called by muse, mutect2, varscan2
- SFPQ | c.1098T>C p.F366= | Silent (SNP) | VAF 88/186 reads (47%) | catalogued as COSV100599428; called by muse, mutect2, varscan2
- SPTLC2 | c.771G>C p.L257= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV99377513; called by muse, mutect2, varscan2
- TBCC | c.384C>A p.R128= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99773958; called by muse, mutect2, varscan2
- TEAD3 | c.1107G>A p.E369= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV100132409; called by muse, mutect2, varscan2
- TMEM145 | c.93C>T p.Y31= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100003853; called by muse, mutect2, varscan2
- TTN | c.46911T>A p.T15637= (on ENST00000591111; = p.T8213= on NM_003319.4) | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV100612369; called by muse, mutect2, varscan2
- AOPEP | c.*5-1221G>T | Intron (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99949716; called by muse, mutect2
- ERCC6 | c.1397+8381T>C | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100875935, COSV63394783; called by muse, mutect2, varscan2
- NOP56 | c.570-161T>A | Intron (SNP) | VAF 31/53 reads (58%) | catalogued as COSV100250104; called by muse, mutect2, varscan2
- TTN | c.10361-5113A>T | Intron (SNP) | VAF 48/118 reads (41%) | catalogued as COSV100612374; called by muse, mutect2, varscan2
